Somatic mutation profile of tumor specimen TCGA-ZF-AA58-01A (aliquot TCGA-ZF-AA58-01A-12D-A42E-08) from TCGA case TCGA-ZF-AA58, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 61.7 years (22,549 days).
Specimen TCGA-ZF-AA58-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abaf44ac-1960-4e5b-a3f6-9cf315c1d60c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA58-10A (Blood Derived Normal), aliquot TCGA-ZF-AA58-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae26543d-712d-459e-9aa2-8fecfbc39132

The open-access MAF lists 236 somatic variants for this specimen: 181 protein-altering or splice-affecting, 50 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 50, Nonsense Mutation 13, Splice Site 5, Splice Region 4, Intron 3, Frame Shift Del 2, Nonstop Mutation 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4241A>G p.Y1414C | Missense Mutation (SNP) | VAF 43/135 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54325155; called by muse, mutect2, varscan2
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AATK | c.2740G>A p.D914N (on ENST00000326724 / NM_001080395.3; = p.D811N on NM_004920.2) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1250513998, COSV58373477; called by muse, mutect2, varscan2
- ABCA9 | c.70T>A p.W24R | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV60631603; called by muse, mutect2, varscan2
- ABCC2 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.664); catalogued as COSV64971367; called by muse, mutect2, varscan2
- ACAN | c.668A>G p.D223G | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61354964; called by muse, mutect2, varscan2
- AGAP1 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV58339791; called by muse, mutect2, varscan2
- AKAP9 | c.8868T>G p.S2956R (on ENST00000359028; = p.S2932R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV62358713; called by muse, mutect2
- AKR1B1 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV53648990, COSV99605287; called by muse, mutect2, varscan2
- ANO10 | c.865C>G p.H289D | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52736717; called by muse, mutect2
- ANXA1 | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV57412858; called by muse, mutect2, varscan2
- ARFGEF1 | c.3848A>G p.H1283R | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as COSV51617569; called by muse, mutect2, varscan2
- ARRDC4 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51418531; called by muse, mutect2, varscan2
- ARSG | c.1002G>C p.Q334H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV71594027; called by muse, mutect2, varscan2
- ASIC3 | c.1571C>A p.T524N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.505); catalogued as COSV52526046; called by muse, mutect2, varscan2
- ATG2A | c.2597C>A p.S866* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as rs1233393498, COSV101033695; called by muse, mutect2
- ATG4D | c.783G>C p.E261D | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as COSV100520949; called by muse, mutect2
- BDP1 | c.5497C>T p.H1833Y | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV62435071; called by muse, mutect2, varscan2
- BMPER | c.754C>G p.L252V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV51825682, COSV51832187; called by muse, mutect2, varscan2
- BUD13 | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.215); catalogued as COSV99496171, COSV99496741; called by muse, mutect2
- BZW1 | c.35C>A p.S12* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV101284528; called by muse, mutect2, varscan2
- C1QA | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV65890107; called by muse, mutect2, varscan2
- C1QTNF1 | c.566T>C p.V189A | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV59264502; called by muse, mutect2, varscan2
- C1S | c.1889G>C p.G630A | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM090218, COSV61072430; called by muse, mutect2
- C3 | c.3262C>G p.L1088V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV55581908; called by muse, mutect2, varscan2
- CA8 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as COSV58773498; called by muse, mutect2, varscan2
- CCSER2 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56513035; called by muse, mutect2, varscan2
- CCT7 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.957); catalogued as COSV57822079, COSV57823955; called by muse, mutect2
- CD22 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | catalogued as COSV99322713; called by muse, mutect2, varscan2
- CD86 | c.642G>A p.M214I (on ENST00000330540 / NM_175862.5; = p.M208I on NM_006889.4) | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV52605187, COSV52610547; called by muse, mutect2, varscan2
- CDH8 | c.861A>C p.E287D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100180964, COSV54902848; called by muse, mutect2, varscan2
- CEBPZ | c.2727A>C p.E909D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as COSV52208697; called by muse, mutect2, varscan2
- CENPJ | c.1638G>C p.M546I | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV67884326; called by muse, mutect2, varscan2
- CES1 | c.1004T>A p.L335H | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62090497; called by muse, mutect2, varscan2
- CFAP221 | c.2425G>C p.D809H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs779719144, COSV54653683, COSV54663387; called by muse, mutect2, varscan2
- CHGB | c.1777C>A p.P593T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV66761861; called by muse, mutect2, varscan2
- CHL1 | c.184A>T p.N62Y | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56607431; called by muse, mutect2, varscan2
- CHRM3 | c.1773G>C p.*591Yext*27 | Nonstop Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99697232; called by muse, mutect2
- CKMT2 | c.1172T>G p.V391G | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54175139; called by muse, mutect2, varscan2
- CLNS1A | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV54440952; called by muse, mutect2, varscan2
- CLVS2 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV51569307; called by muse, mutect2, varscan2
- CMYA5 | c.9184A>T p.N3062Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71409754; called by muse, mutect2
- CNNM3 | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs926624351, COSV59710008; called by muse, mutect2, varscan2
- COLGALT2 | c.1625A>G p.Y542C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100730303; called by muse, mutect2
- CUL4B | c.1691-2A>C p.X564_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | catalogued as COSV60691409; called by muse, mutect2, varscan2
- CYP3A4 | c.1543C>G p.Q515E (on ENST00000336411; = p.Q484E on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV60504444; called by muse, mutect2
- DCAF4L1 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 25/154 reads (16%) | catalogued as COSV60788067; called by muse, mutect2, varscan2
- DCHS1 | c.5844C>G p.I1948M | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs768802065, COSV55043339; called by muse, mutect2, varscan2
- DDAH1 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as COSV52308384; called by muse, mutect2, varscan2
- DDX23 | c.2407C>T p.H803Y | Missense Mutation (SNP) | VAF 3/63 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.543); catalogued as rs899694983, COSV99974579; called by muse, mutect2
- DENND5B | c.1179C>G p.I393M | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as COSV60908801; called by muse, mutect2, varscan2
- DICER1 | c.4803G>C p.K1601N | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58628889; called by muse, mutect2, varscan2
- DNAH5 | c.5697C>G p.I1899M | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54244631, COSV54247801; called by muse, mutect2
- EFCAB5 | c.4215G>T p.K1405N | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV100299644; called by muse, mutect2
- ELMO2 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV51681662; called by muse, mutect2, varscan2
- ELOA | c.1837G>C p.D613H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV69311441; called by muse, mutect2
- EPB41L4B | c.750C>T p.C250= | Splice Region (SNP) | VAF 11/80 reads (14%) | catalogued as COSV65798937; called by muse, mutect2, varscan2
- ERCC6L2 | c.4123G>A p.A1375T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs1451398513; called by muse, mutect2, varscan2
- EXPH5 | c.3332G>C p.R1111T | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56201263, COSV56208796; called by muse, mutect2, varscan2
- FBXW8 | c.7-1G>A p.X3_splice (on ENST00000309909; = p.X41_splice on NM_012174.1) | Splice Site (SNP) | VAF 8/52 reads (15%) | catalogued as rs141082626; called by muse, mutect2
- FMN2 | c.2635C>A p.P879T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as rs1217064564, COSV60432948; called by muse, mutect2, varscan2
- FREM2 | c.4322C>T p.T1441I | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs980772391, COSV54853699; called by muse, mutect2, varscan2
- FSTL4 | c.1289T>C p.I430T | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs772554372, COSV54786852; called by muse, mutect2, varscan2
- FYB2 | c.37C>G p.R13G | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58589627; called by muse, mutect2
- GABRG1 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs369652618; called by muse, mutect2, varscan2
- GALNT13 | c.284G>T p.R95I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1481627474, COSV101222602, COSV67215270, COSV67240330; called by muse, mutect2, varscan2
- GJA3 | c.596A>G p.E199G | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1410336, COSV99576232; called by muse, mutect2
- GNAS | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV55688555; called by muse, mutect2, varscan2
- GPAA1 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.469); catalogued as rs1554763825, COSV60156581; called by muse, mutect2, varscan2
- GRIN2C | c.3685C>G p.L1229V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as COSV53118253, COSV99501173; called by muse, mutect2
- GTF3C4 | c.1241A>G p.H414R | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV64646227; called by muse, mutect2, varscan2
- GUCY2C | c.3066G>C p.L1022F | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53795954; called by muse, mutect2, varscan2
- H2AC16 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.505); catalogued as rs1177803561, COSV58901606; called by muse, mutect2, varscan2
- HDLBP | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV60501233; called by muse, mutect2, varscan2
- HEATR5B | c.5469_5470del p.E1824Gfs*13 | Frame Shift Del (DEL) | VAF 15/114 reads (13%) | catalogued as COSV51859480; called by mutect2, pindel, varscan2
- HLF | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1471376401, COSV56828836; called by muse, mutect2, varscan2
- HPSE2 | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65202576; called by muse, mutect2, varscan2
- HSPA12A | c.1710G>C p.K570N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV65024004; called by muse, mutect2, varscan2
- IFNE | c.450G>T p.R150S | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV58644340; called by muse, mutect2, varscan2
- IFNE | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as COSV58644347; called by muse, mutect2, varscan2
- IGBP1P2 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV53626952; called by muse, mutect2, varscan2
- IL6ST | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV61140498, COSV61141939; called by muse, mutect2
- INTS6L | c.805C>G p.H269D | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV66086545; called by muse, mutect2, varscan2
- INTS7 | c.372G>A p.R124= | Splice Region (SNP) | VAF 18/87 reads (21%) | catalogued as COSV65345123, COSV65345612; called by muse, mutect2, varscan2
- KCNJ15 | c.320G>A p.C107Y | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60812076; called by muse, mutect2, varscan2
- KIF14 | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 24/153 reads (16%) | catalogued as COSV100950561; called by muse, mutect2, varscan2
- KIF1B | c.1594C>G p.P532A (on ENST00000377086 / NM_001365952.1; = p.P486A on NM_015074.3) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs201500946; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF5B | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100191226; called by muse, mutect2
- KIF5C | c.2473G>C p.G825R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV68484072; called by muse, mutect2
- KMT2D | c.1657C>G p.P553A | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.168); catalogued as COSV56424212, COSV56489850; called by muse, mutect2, varscan2
- KRT72 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53377022; called by muse, mutect2, varscan2
- LAMA4 | c.5008T>A p.F1670I (on ENST00000230538 / NM_001105206.3; = p.F1663I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57905593; called by muse, mutect2, varscan2
- LAMB1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV55970642; called by muse, mutect2, varscan2
- LAX1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65848880, COSV65850195; called by muse, mutect2
- LINGO2 | c.1693G>T p.V565L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV58059919, COSV58064915; called by muse, mutect2, varscan2
- LONRF2 | c.1483G>C p.A495P | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV66542588; called by muse, mutect2
- LRIG1 | c.3098C>A p.S1033Y | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.123); catalogued as COSV56248677; called by muse, mutect2
- LRP1B | c.11133C>G p.V3711= | Splice Region (SNP) | VAF 9/83 reads (11%) | catalogued as COSV67278324; called by muse, mutect2, varscan2
- LRRC39 | c.813-1G>C p.X271_splice | Splice Site (SNP) | VAF 11/81 reads (14%) | catalogued as rs768644922, COSV61584180; called by muse, mutect2, varscan2
- LRRFIP1 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs1433108359, COSV57833998; called by muse, mutect2, varscan2
- LYPD6 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.219); catalogued as COSV61938392, COSV61942525; called by muse, mutect2, varscan2
- MACROD2 | c.310T>G p.C104G | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs946213066, COSV54059916; called by muse, mutect2
- MAGEA1 | c.208T>G p.F70V | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.173); catalogued as COSV63119330; called by muse, mutect2, varscan2
- MAPRE2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55821749; called by muse, mutect2
- MARS1 | c.905A>C p.Q302P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV56258887; called by mutect2, varscan2
- MAST2 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as COSV63621566; called by muse, mutect2, varscan2
- MASTL | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as COSV60912734; called by muse, mutect2, varscan2
- MBD4 | c.618C>G p.N206K | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.212); catalogued as COSV51445941; called by muse, mutect2, varscan2
- MEDAG | c.827G>C p.R276T | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs1469991374, COSV66850953; called by muse, mutect2
- MEGF9 | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV64238047; called by muse, mutect2
- MET | c.3370T>C p.F1124L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59269822; called by muse, mutect2, varscan2
- MGAT5 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV56101541; called by muse, varscan2
- MGME1 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV66624821; called by muse, mutect2, varscan2
- MIA3 | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV60518391; called by muse, mutect2, varscan2
- MIS18BP1 | c.1652A>T p.H551L | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV60373697; called by muse, mutect2
- MMP2 | c.1287G>C p.K429N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs201083413, CD161171, COSV54605568; called by muse, mutect2, varscan2
- MTHFD1 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53704076; called by muse, mutect2, varscan2
- MYCBP2 | c.10319C>T p.S3440L (on ENST00000357337; = p.S3478L on NM_015057.5) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV62040462; called by muse, mutect2, varscan2
- MYO16 | c.3034G>C p.D1012H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV62762706; called by muse, mutect2, varscan2
- MYOM1 | c.2929G>C p.D977H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.943); catalogued as COSV55301814; called by muse, mutect2
- MYOM2 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs370995476; called by muse, mutect2, varscan2
- NALCN | c.3631T>C p.F1211L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV51960782, COSV51967447; called by muse, mutect2, varscan2
- NEURL4 | c.3775C>A p.H1259N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV59753485; called by muse, mutect2, varscan2
- NFATC1 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53710087; called by muse, mutect2, varscan2
- NPR3 | c.1059C>T p.Y353= | Splice Region (SNP) | VAF 14/49 reads (29%) | catalogued as rs373766629; called by muse, mutect2, varscan2
- NSD3 | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57622208; called by muse, mutect2, varscan2
- NUP205 | c.4714G>C p.E1572Q | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.958); catalogued as COSV53666640; called by muse, mutect2, varscan2
- OBSCN | c.3394G>A p.V1132M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs747695006, COSV52833542; called by muse, mutect2
- OGA | c.2254G>C p.G752R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100761658, COSV63383486; called by muse, mutect2, varscan2
- OPTN | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53813456; called by muse, mutect2, varscan2
- OTUB1 | c.791G>C p.G264A | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55367804; called by muse, mutect2
- PCDHB14 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV53391512; called by muse, mutect2, varscan2
- PDE3A | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62983492; called by muse, mutect2, varscan2
- PDE3B | c.2366C>T p.S789L | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1439125865, COSV56379909; called by muse, mutect2, varscan2
- PHF20L1 | c.2065G>C p.D689H | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55198813; called by muse, mutect2
- PRAM1 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs761767348, COSV55317340; called by muse, mutect2, varscan2
- PTGER3 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as rs777755530, COSV60690336; called by muse, mutect2, varscan2
- QRICH1 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV62617764; called by muse, mutect2, varscan2
- RB1 | c.2308C>T p.Q770* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as CM030516, COSV57295380; called by muse, mutect2, varscan2
- RING1 | c.563C>G p.S188* | Nonsense Mutation (SNP) | VAF 14/87 reads (16%) | catalogued as COSV100761707, COSV63002853; called by muse, mutect2
- ROBO4 | c.2474C>A p.P825H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV60628220; called by muse, mutect2, varscan2
- ROPN1L | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99928504, COSV99928614; called by muse, mutect2, varscan2
- RPAP1 | c.634G>C p.G212R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100426815, COSV58542669; called by mutect2, varscan2
- RPRD2 | c.3791G>C p.G1264A | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV64823489; called by muse, mutect2, varscan2
- SEL1L2 | c.894G>C p.Q298H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53158745; called by muse, mutect2, varscan2
- SETD5 | c.2437G>C p.E813Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as COSV56717687; called by muse, mutect2
- SIPA1L1 | c.5126C>T p.A1709V | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV62173936; called by muse, mutect2, varscan2
- SLC37A3 | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV58268911; called by muse, mutect2
- SMPDL3A | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV63755879; called by muse, mutect2, varscan2
- SQLE | c.376G>C p.V126L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.434); catalogued as COSV56282797; called by muse, mutect2, varscan2
- STAB1 | c.6923G>A p.R2308Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs777490339, COSV58743547; called by muse, mutect2, varscan2
- STIM2 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52838076; called by muse, mutect2, varscan2
- STK32B | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51514779; called by muse, mutect2, varscan2
- STOML2 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs1159451078, COSV59717663; called by muse, mutect2, varscan2
- TCN1 | c.1280A>G p.E427G | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV57254817; called by muse, mutect2, varscan2
- TDO2 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as rs374938550, COSV72233156; called by muse, mutect2, varscan2
- TDRD3 | c.1305T>A p.Y435* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99539605; called by muse, mutect2, varscan2
- TEK | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV66231598; called by muse, mutect2, varscan2
- TEP1 | c.3108-2A>C p.X1036_splice | Splice Site (SNP) | VAF 10/85 reads (12%) | catalogued as COSV53000829; called by muse, mutect2, varscan2
- TMEM200A | c.1397C>G p.S466C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51660210; called by muse, mutect2, varscan2
- TMEM63A | c.1874G>C p.S625T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100834206, COSV64764012; called by muse, mutect2
- TRMT2B | c.1152G>C p.W384C | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV58621265; called by muse, mutect2, varscan2
- TRPC3 | c.2479C>A p.Q827K (on ENST00000379645 / NM_001366479.2; = p.Q754K on NM_003305.2) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV53381825; called by muse, mutect2, varscan2
- TUBB2B | c.56A>T p.K19M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV52534553; called by muse, mutect2, varscan2
- TUFT1 | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); catalogued as COSV61948792; called by muse, mutect2, varscan2
- UBE2O | c.3355C>G p.P1119A | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1169903245, COSV60067948; called by muse, mutect2
- USP53 | c.284C>G p.S95* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as COSV99917448; called by muse, mutect2
- XIRP1 | c.4858G>T p.E1620* | Nonsense Mutation (SNP) | VAF 32/129 reads (25%) | catalogued as COSV100453247; called by muse, mutect2, varscan2
- XIRP2 | c.4496A>C p.K1499T (on ENST00000628543; = p.K1674T on NM_152381.6) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54725963, COSV54736542; called by muse, mutect2, varscan2
- ZFHX4 | c.4085A>C p.K1362T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV51498248; called by muse, mutect2, varscan2
- ZFP30 | c.294G>C p.M98I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63622490, COSV63623171; called by muse, mutect2, varscan2
- ZMIZ1 | c.3193G>C p.E1065Q | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV57904374; called by muse, mutect2, varscan2
- ZNF248 | c.1346C>G p.S449* | Nonsense Mutation (SNP) | VAF 19/145 reads (13%) | catalogued as COSV100627448; called by muse, mutect2, varscan2
- ZNF564 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV59436737; called by muse, mutect2, varscan2
- ZNF626 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs1555769327, COSV74131002; called by muse, varscan2
- ZNF626 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV74128857; called by muse, varscan2
- PIGW | c.759G>C p.L253F | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); called by muse, mutect2
- TRAV6 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- VPS52 | c.1729-2_1766del p.X577_splice | Splice Site (DEL) | VAF 6/78 reads (8%) | called by mutect2, pindel
- ZBTB8OS | c.410del p.S137* | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- ABL1 | c.1134G>A p.K378= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as rs1298439117, COSV59341858; called by muse, mutect2
- AFF2 | c.3453G>T p.G1151= | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as COSV54008854; called by muse, mutect2, varscan2
- ARHGAP36 | c.876A>C p.A292= | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as COSV52272436; called by muse, mutect2, varscan2
- ATP4A | c.363C>T p.I121= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV52872090; called by muse, mutect2
- CD6 | c.1371C>T p.I457= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV57843022; called by muse, mutect2, varscan2
- CEACAM7 | c.126G>A p.P42= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs782565655, COSV50075191; called by muse, mutect2, varscan2
- CES1 | c.1005T>A p.L335= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV62090487; called by muse, mutect2, varscan2
- DDX3X | c.1527G>A p.V509= (on ENST00000399959; = p.V510= on NM_001356.5) | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV67864605; called by muse, mutect2
- DENND2C | c.2406G>A p.L802= (on ENST00000393274 / NM_001256404.2; = p.L745= on NM_198459.4) | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV67924193; called by muse, mutect2, varscan2
- DNAAF3 | c.714C>T p.V238= (on ENST00000524407 / NM_001256715.2; = p.V285= on NM_178837.4) | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1264672206, COSV61279658; called by muse, mutect2, varscan2
- DOP1A | c.2073C>G p.L691= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV52718781; called by muse, mutect2, varscan2
- DOP1B | c.3954C>T p.L1318= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs1266669814, COSV67694444; called by muse, mutect2, varscan2
- EPHB3 | c.687G>A p.A229= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs747329213, COSV57809479; called by muse, varscan2
- FAM78A | c.429C>T p.T143= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV55993408; called by muse, mutect2, varscan2
- FBN2 | c.6261T>C p.F2087= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV52546669; called by muse, mutect2, varscan2
- FYN | c.108T>G p.P36= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV57621720; called by muse, mutect2, varscan2
- GATA5 | c.1125C>T p.A375= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV53347552; called by muse, mutect2, varscan2
- GJA5 | c.609G>A p.E203= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV54786825; called by muse, mutect2
- GPRC5D | c.135C>G p.L45= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV57433523; called by muse, mutect2, varscan2
- GRXCR1 | c.504A>G p.V168= | Silent (SNP) | VAF 53/197 reads (27%) | catalogued as COSV67674951; called by muse, mutect2, varscan2
- HOXA6 | c.255C>T p.L85= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV56075018; called by muse, mutect2
- INKA2 | c.618G>C p.L206= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- IQCN | c.468G>A p.T156= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs774117177, COSV66575582; called by muse, mutect2
- IRS4 | c.1551G>A p.S517= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as COSV64532774, COSV64536071; called by muse, mutect2, varscan2
- KANK1 | c.435A>G p.P145= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV63216514; called by muse, mutect2, varscan2
- LRP1 | c.9228G>A p.V3076= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs755868917, COSV54527215; called by muse, mutect2, varscan2
- MAGEA3 | c.585C>T p.I195= | Silent (SNP) | VAF 20/187 reads (11%) | catalogued as COSV64756555; called by muse, mutect2, varscan2
- MAGI1 | c.3345A>G p.A1115= (on ENST00000402939 / NM_001033057.2; = p.A1144= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100443403, COSV58346196; called by muse, mutect2, varscan2
- MDN1 | c.3201A>G p.R1067= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV65530869; called by muse, mutect2, varscan2
- MOCOS | c.1203C>T p.I401= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV54347045; called by muse, mutect2, varscan2
- MSS51 | c.777G>A p.R259= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV55020864; called by muse, mutect2
- NEURL4 | c.4071C>T p.F1357= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV59750165; called by muse, mutect2, varscan2
- OR2A14 | c.111C>A p.T37= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV68718726; called by muse, mutect2, varscan2
- PARP14 | c.1662C>T p.F554= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV101506211, COSV71734086; called by muse, mutect2
- PCDHGA1 | c.1626C>T p.L542= | Silent (SNP) | VAF 35/227 reads (15%) | catalogued as COSV65300011; called by muse, mutect2, varscan2
- PIK3R1 | c.1887C>T p.S629= (on ENST00000521381 / NM_181523.3; = p.S359= on NM_181504.4) | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV57140616; called by muse, mutect2, varscan2
- PROX1 | c.486G>A p.L162= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs1435696085, COSV54779364; called by muse, mutect2, varscan2
- PTGFR | c.607C>T p.L203= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV66116880; called by muse, mutect2, varscan2
- RNF123 | c.1197C>T p.G399= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV59692767; called by muse, mutect2
- RNF17 | c.2175C>G p.L725= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV55052389, COSV99694254; called by muse, mutect2, varscan2
- SIGLEC9 | c.507C>T p.A169= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs147990048, COSV51588807; called by muse, mutect2, varscan2
- SLC25A25 | c.249G>A p.L83= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV66087365; called by muse, mutect2, varscan2
- SLC31A1 | c.273G>A p.E91= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV65265113; called by muse, mutect2, varscan2
- SPTBN1 | c.2460G>T p.V820= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV61694587; called by muse, mutect2, varscan2
- SSTR2 | c.45A>G p.L15= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV59536154; called by muse, mutect2
- TARS2 | c.549G>A p.R183= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV64694806; called by muse, mutect2, varscan2
- TBL1X | c.1731G>A p.K577= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV54289338; called by muse, mutect2, varscan2
- TSHZ3 | c.1881G>A p.K627= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV53683676; called by muse, mutect2, varscan2
- VWCE | c.2268C>A p.S756= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs773320665, COSV57113480, COSV57115638; called by muse, mutect2, varscan2
- ZFC3H1 | c.4017C>T p.Y1339= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs762973148, COSV66436118; called by muse, mutect2, varscan2
- ADGRG6 | c.*112C>T | 3'UTR (SNP) | VAF 12/73 reads (16%) | catalogued as COSV51601571; called by muse, mutect2, varscan2
- CKS1B | c.59+106G>C | Intron (SNP) | VAF 14/102 reads (14%) | catalogued as rs937451790, COSV58316909; called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442670 G>C | 3'Flank (SNP) | VAF 4/33 reads (12%) | catalogued as COSV62635702; called by muse, mutect2, varscan2
- RGS3 | c.415+1654A>T | Intron (SNP) | VAF 6/35 reads (17%) | catalogued as COSV58285923; called by mutect2, varscan2
- RORC | c.70+3497G>A | Intron (SNP) | VAF 8/92 reads (9%) | catalogued as COSV59095967; called by muse, mutect2
